Somatic mutation profile of tumor specimen ALCH-B2T1-TTP1-A (aliquot ALCH-B2T1-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2T1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.4 years (23,517 days).
Specimen ALCH-B2T1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35b0b520-c3df-4496-b772-3a795b2e23e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2T1-NB1-A (Blood Derived Normal), aliquot ALCH-B2T1-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea027914-a50d-4132-874f-fc6c7b822787

The open-access MAF lists 55 somatic variants for this specimen: 35 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 14, 3'UTR 3, Intron 3, Splice Site 1, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 50/284 reads (18%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- ATM | c.7354C>G p.L2452V | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs587779863, COSV53746636; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRA5 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.75); catalogued as rs775162132, COSV100164665; called by muse, mutect2
- HLX | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 10/263 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1321310977, COSV65044717; called by muse, mutect2
- MARCHF8 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751632778, COSV60570657; called by muse, mutect2
- MYLK | c.4459C>G p.R1487G | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs886229659, CM158147; called by muse, mutect2
- NRXN2 | c.4000del p.E1334Rfs*52 | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | catalogued as COSV55454418; called by mutect2, pindel, varscan2
- PDGFRB | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.947); catalogued as rs754451292, COSV55801133; called by muse, mutect2
- PLCH1 | c.2374G>A p.E792K (on ENST00000340059 / NM_001130960.2; = p.E804K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780182537, COSV100397543; called by muse, mutect2, varscan2
- SZT2 | c.3880G>A p.A1294T (on ENST00000634258 / NM_001365999.1; = p.A1237T on NM_015284.4) | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV65167817; called by muse, mutect2, varscan2
- TLK2 | c.1405G>A p.G469S (on ENST00000326270 / NM_001284333.2; = p.G447S on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs770965243; called by muse, mutect2, varscan2
- ZNF440 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV58371926; called by muse, mutect2, varscan2
- ANXA8 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ATG2B | c.1113C>A p.N371K | Missense Mutation (SNP) | VAF 38/325 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CPD | c.2286A>C p.E762D | Missense Mutation (SNP) | VAF 11/224 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2
- CPSF3 | c.1856+2T>G p.X619_splice | Splice Site (SNP) | VAF 25/108 reads (23%) | called by muse, mutect2, varscan2
- DNAH6 | c.6958C>G p.Q2320E | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DYNLRB1 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- FAN1 | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FCRL5 | c.741T>G p.I247M | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- HROB | c.1818A>C p.E606D | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- IFNA7 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- IL37 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- KLF17 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, varscan2
- MCTS1 | c.75T>G p.I25M | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- MYH3 | c.995C>A p.A332D | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2
- PEDS1 | c.715A>C p.K239Q | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.018); called by muse, mutect2
- PPFIA3 | c.1807G>A p.A603T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RECQL5 | c.2878A>G p.K960E | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- REV1 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D12 | c.2107A>G p.I703V | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.669); called by muse, mutect2
- TBC1D8B | c.2836G>A p.E946K | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE2R2 | c.226A>T p.R76* | Nonsense Mutation (SNP) | VAF 9/202 reads (4%) | called by muse, mutect2
- UBR4 | c.13393G>A p.E4465K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- WDTC1 | c.1213G>A p.A405T (on ENST00000319394 / NM_001276252.2; = p.A404T on NM_015023.5) | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); called by muse, mutect2
- CACNA1A | c.4032G>A p.T1344= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as rs370735316; called by muse, mutect2
- CASK | c.324C>T p.D108= | Silent (SNP) | VAF 24/491 reads (5%) | catalogued as rs775952248; called by muse, mutect2
- CPS1 | c.2253G>A p.K751= | Silent (SNP) | VAF 40/170 reads (24%) | catalogued as COSV51802122; called by muse, mutect2, varscan2
- CRK | c.183C>T p.I61= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- FNIP2 | c.2610C>A p.I870= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100032203; called by muse, mutect2, varscan2
- KLF17 | c.786A>G p.V262= | Silent (SNP) | VAF 12/155 reads (8%) | catalogued as rs1235313973; called by muse, mutect2
- KRTAP21-2 | c.108C>A p.G36= | Silent (SNP) | VAF 20/258 reads (8%) | called by muse, mutect2
- NCKAP5L | c.3276G>A p.G1092= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs1289281090; called by muse, mutect2, varscan2
- OPRK1 | c.813G>A p.R271= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV55571827; called by muse, mutect2, varscan2
- OR14A2 | c.468G>A p.A156= | Silent (SNP) | VAF 13/120 reads (11%) | catalogued as rs547988475, COSV63573191; called by muse, mutect2
- OR2A5 | c.459C>G p.S153= | Silent (SNP) | VAF 40/158 reads (25%) | catalogued as COSV68738779; called by muse, mutect2, varscan2
- PTK2 | c.2259C>T p.I753= | Silent (SNP) | VAF 18/200 reads (9%) | catalogued as COSV61785770; called by muse, mutect2
- PWWP3A | c.684G>A p.L228= (on ENST00000627377; = p.L227= on NM_032853.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- ZNF469 | c.7776C>T p.T2592= (on ENST00000437464; = p.T2620= on NM_001367624.2) | Silent (SNP) | VAF 13/170 reads (8%) | catalogued as rs1438352502, COSV71258933; called by muse, mutect2
- CBX2 | c.288+213C>A | Intron (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- CLSTN3 | c.2528-994A>G | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- DCHS1 | c.*148C>T | 3'UTR (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- PLCB4 | c.1612-2569G>A | Intron (SNP) | VAF 7/88 reads (8%) | catalogued as rs990273337; called by muse, mutect2
- SFTPB | c.*1_*3del | 3'UTR (DEL) | VAF 5/45 reads (11%) | called by pindel, varscan2
- SHROOM4 | c.*1025C>T | 3'UTR (SNP) | VAF 16/501 reads (3%) | called by muse, mutect2
